Gene-level copy-number profile of specimen HCM-CSHL-0151-C50-85A from HCMI case HCM-CSHL-0151-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 42.3 years (15,434 days).
Specimen HCM-CSHL-0151-C50-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 13.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file abe34ab0-6d30-4195-a2ea-2b3614d101a7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0151-C50-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/8dd0489a-3145-4929-a8c1-6f3bdb422347

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,409; copy number 2: 48,990; copy number 3: 1,478; copy number 4: 2,524.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
